Somatic mutation profile of tumor specimen TCGA-FT-A3EE-01A (aliquot TCGA-FT-A3EE-01A-11D-A202-08) from TCGA case TCGA-FT-A3EE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder neck; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 80.2 years (29,293 days).
Specimen TCGA-FT-A3EE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09bce571-5759-4248-a6c2-01d6b940fb1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FT-A3EE-10A (Blood Derived Normal), aliquot TCGA-FT-A3EE-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/137a5cd0-6953-4eae-988a-0ebb6ff84b5a

The open-access MAF lists 146 somatic variants for this specimen: 112 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 31, Nonsense Mutation 6, Splice Site 3, Frame Shift Ins 2, Frame Shift Del 2, 5'UTR 2, Intron 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 44/88 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC011448.1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs773721950; called by muse, mutect2
- ACOX3 | c.554T>C p.I185T | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1454673421, COSV62711840; called by muse, mutect2, varscan2
- ADGRV1 | c.7446C>A p.Y2482* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV67980104; called by muse, mutect2, varscan2
- AGRN | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV65069306; called by muse, mutect2, varscan2
- ALLC | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.197); catalogued as COSV52994330, COSV52994675; called by muse, mutect2, varscan2
- ARHGAP35 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV68330374, COSV68330872; called by muse, mutect2, varscan2
- ARHGAP6 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV57295311; called by muse, mutect2, varscan2
- ARMC3 | c.2441C>G p.S814C | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV53060605; called by muse, mutect2, varscan2
- ATF6 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV63407310, COSV63409289; called by muse, mutect2, varscan2
- ATM | c.851A>C p.Q284P | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV53741317; called by muse, mutect2, varscan2
- ATP13A3 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV55464153; called by muse, mutect2, varscan2
- B3GNT4 | c.19T>G p.S7A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV57336221; called by muse, mutect2, varscan2
- BAMBI | c.387T>A p.H129Q | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV65002945; called by muse, mutect2, varscan2
- BRCA2 | c.575T>C p.M192T | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs80358805, CM021250, COSV66453006; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign; called by muse, mutect2, varscan2
- BRWD1 | c.5801C>T p.T1934M | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs779526219, COSV60895200; called by muse, mutect2, varscan2
- BTNL9 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs746350412, COSV59795618; called by muse, varscan2
- CCDC74B | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs372108145; called by muse, mutect2, varscan2
- CCM2 | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV51848059, COSV51848339; called by muse, mutect2, varscan2
- CDC25A | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); catalogued as COSV56770501; called by muse, mutect2, varscan2
- CDC42BPB | c.1535A>C p.E512A | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV63474793, COSV63476964; called by muse, mutect2, varscan2
- CELSR3 | c.7885C>T p.R2629C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751920709, COSV50854705; called by muse, mutect2, varscan2
- CETN2 | c.396G>T p.E132D | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs1556842933, COSV64743779; called by muse, mutect2, varscan2
- CHGB | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV66760354; called by muse, mutect2, varscan2
- COL2A1 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs767149878, COSV61533365; called by muse, mutect2, varscan2
- CRCT1 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | PolyPhen possibly damaging (0.648); catalogued as COSV100524339; called by muse, varscan2
- DCLK3 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs780144006, COSV69363027; called by muse, mutect2, varscan2
- DDX5 | c.1643A>G p.N548S | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV56748983; called by muse, mutect2, varscan2
- DIDO1 | c.2133T>A p.F711L | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV56621054; called by muse, mutect2, varscan2
- DISP1 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs774959288, COSV52658258; called by muse, mutect2, varscan2
- DNAH2 | c.12404C>T p.S4135F | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV66719021; called by muse, mutect2, varscan2
- DPF1 | c.502T>C p.C168R | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.248); catalogued as COSV62792667; called by muse, mutect2, varscan2
- ECPAS | c.3367C>A p.R1123S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52196330; called by muse, mutect2, varscan2
- ENO3 | c.1014C>A p.N338K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV52777237; called by muse, mutect2, varscan2
- ERCC2 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55540161; called by muse, mutect2, varscan2
- ERN2 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436655757, COSV56833403, COSV99892701; called by muse, mutect2, varscan2
- FAHD2A | c.424G>C p.G142R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51978077; called by muse, mutect2, varscan2
- FAM47B | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773277904; called by muse, mutect2, varscan2
- GPR37 | c.1530C>G p.I510M | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58256077, COSV58256681; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2589G>C p.E863D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1456759351; called by mutect2, varscan2
- HSD17B11 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1400539294, COSV64154329; called by muse, mutect2, varscan2
- ITGA2B | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs780392176, COSV52232399; called by muse, mutect2, varscan2
- KHSRP | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs763165761, COSV67919647, COSV67920225; called by muse, mutect2
- KMT2B | c.8135G>A p.R2712Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs766722222, COSV53074720; called by muse, mutect2, varscan2
- LINGO3 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68261274; called by muse, mutect2, varscan2
- LMLN | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV57600475; called by muse, mutect2, varscan2
- LRRN1 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs750597257, COSV60013677, COSV60014895; called by muse, mutect2, varscan2
- LTA4H | c.1745A>G p.H582R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748793205, COSV54117598; called by muse, mutect2, varscan2
- LYST | c.9334C>G p.H3112D | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV67706541; called by muse, mutect2, varscan2
- MAGI2 | c.962T>C p.I321T | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62653184; called by muse, mutect2, varscan2
- MARF1 | c.3475-1G>A p.X1159_splice | Splice Site (SNP) | VAF 25/53 reads (47%) | catalogued as COSV60022906; called by muse, mutect2, varscan2
- MED12 | c.3652G>A p.G1218R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61338713, COSV61356928; called by muse, mutect2
- MESD | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs758532744, COSV55725035; called by muse, mutect2, varscan2
- MIPEP | c.2099A>G p.D700G | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV66300428; called by muse, mutect2, varscan2
- MLNR | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (0.8); PolyPhen benign (0.06); catalogued as rs998496207, COSV54531774; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1378T>A p.L460I | Missense Mutation (SNP) | VAF 95/287 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54914627; called by muse, mutect2, varscan2
- MRPS10 | c.237G>C p.L79F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV50002544; called by muse, mutect2, varscan2
- MYCBP2 | c.5317G>A p.D1773N (on ENST00000357337; = p.D1811N on NM_015057.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs374987058, COSV62024502; called by muse, mutect2, varscan2
- MYH8 | c.4705A>T p.N1569Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV67964252; called by muse, mutect2, varscan2
- MYOZ1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV63771853; called by muse, mutect2, varscan2
- NOA1 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51736768; called by muse, mutect2, varscan2
- NUB1 | c.119G>T p.R40M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63426499; called by muse, mutect2, varscan2
- OR56B4 | c.914T>A p.L305Q | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57204469; called by muse, mutect2, varscan2
- OXCT2 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1159718365, COSV59593762; called by muse, mutect2, varscan2
- PAK2 | c.410A>C p.Q137P | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV59081054; called by muse, mutect2, varscan2
- PCDHA2 | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV65366037; called by muse, mutect2, varscan2
- PCDHB1 | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV60630658; called by muse, mutect2, varscan2
- PCDHGA12 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV52750613; called by muse, mutect2, varscan2
- PCLO | c.9565G>A p.E3189K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs549114733, COSV61622616; called by muse, mutect2, varscan2
- PDE4DIP | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV57693012; called by muse, mutect2, varscan2
- PIK3C2G | c.2731G>A p.D911N (on ENST00000676171; = p.D870N on NM_004570.5) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as COSV56807594, COSV56810527; called by muse, mutect2, varscan2
- POM121L12 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV68692858; called by muse, mutect2, varscan2
- PPRC1 | c.4349C>T p.S1450L | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs1564957247, COSV53385011; called by muse, mutect2, varscan2
- PRKDC | c.11893C>T p.R3965C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs775955634, COSV58050838; called by muse, mutect2, varscan2
- PRPF38B | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1557770634, COSV100898315, COSV100898328; called by muse, mutect2, varscan2
- PSD2 | c.943C>G p.H315D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV51199231, COSV51203252; called by muse, mutect2, varscan2
- PWWP2A | c.1036T>C p.S346P | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61046062; called by muse, mutect2, varscan2
- RAB37 | c.433G>T p.A145S (on ENST00000392613 / NM_001006638.3; = p.A138S on NM_175738.5) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.219); catalogued as COSV52853135; called by muse, mutect2, varscan2
- RANBP9 | c.1469A>G p.H490R | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1359609934, COSV50581028; called by muse, mutect2, varscan2
- RARG | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58432760; called by muse, mutect2, varscan2
- RNLS | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64264116; called by muse, mutect2, varscan2
- RSBN1 | c.731A>G p.Q244R | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.969); catalogued as COSV54732232; called by muse, mutect2, varscan2
- S100A5 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63296809; called by muse, mutect2, varscan2
- SAMHD1 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV53429420; called by muse, mutect2, varscan2
- SCNN1G | c.1338G>T p.E446D | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as COSV55598604; called by muse, mutect2, varscan2
- SLC35E4 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as rs1186469821, COSV55898986; called by muse, mutect2, varscan2
- SMARCA1 | c.1099-2A>G p.X367_splice | Splice Site (SNP) | VAF 26/61 reads (43%) | catalogued as COSV64411763; called by muse, mutect2, varscan2
- SPTA1 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV63752400; called by muse, mutect2
- TASOR | c.3632T>C p.L1211S (on ENST00000355628 / NM_001365636.2; = p.L835S on NM_015224.3) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as COSV62927646; called by muse, mutect2, varscan2
- TC2N | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV61746896; called by muse, mutect2, varscan2
- TEX15 | c.4318G>T p.D1440Y (on ENST00000256246; = p.D1823Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV56345662; called by muse, mutect2, varscan2
- TMEM255B | c.943T>C p.F315L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV64712488; called by muse, mutect2, varscan2
- TNK2 | c.1417C>G p.R473G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.673); catalogued as COSV100361934, COSV57368906; called by muse, mutect2, varscan2
- TSHZ3 | c.2558A>T p.N853I | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as COSV53670396; called by muse, mutect2, varscan2
- TSPAN16 | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57442145, COSV57443551; called by muse, mutect2, varscan2
- VAMP4 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV52561079; called by muse, mutect2, varscan2
- VIT | c.1210G>T p.G404C (on ENST00000389975 / NM_001177969.1; = p.G419C on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64896519; called by muse, mutect2, varscan2
- WDR45 | c.436+1G>A p.X146_splice (on ENST00000376372 / NM_001029896.2; = p.X147_splice on NM_007075.3) | Splice Site (SNP) | VAF 4/80 reads (5%) | catalogued as CS132357, COSV59876327; called by muse, mutect2
- ZC3H18 | c.943_944dup p.T316Qfs*18 | Frame Shift Ins (INS) | VAF 31/153 reads (20%) | catalogued as COSV56322443; called by mutect2, pindel, varscan2
- ZDBF2 | c.542dup p.V182Sfs*4 | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | catalogued as rs781132593; called by mutect2, pindel, varscan2
- ZNF37A | c.1019C>G p.S340* | Nonsense Mutation (SNP) | VAF 38/131 reads (29%) | catalogued as COSV61073207; called by muse, varscan2
- ZNF502 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV56073201; called by muse, mutect2, varscan2
- ZNF862 | c.2102T>C p.M701T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1354140761, COSV56224583; called by muse, mutect2
- CD37 | c.715_750del p.H239_L250del | In Frame Del (DEL) | VAF 32/299 reads (11%) | called by mutect2, pindel
- FBXO38 | c.487_491del p.H163Ffs*6 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- GLI3 | c.3640C>T p.Q1214* | Nonsense Mutation (SNP) | VAF 49/119 reads (41%) | called by muse, mutect2, varscan2
- KCNA1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- RHBDD1 | c.850del p.D284Tfs*21 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- SLC43A2 | c.565T>C p.S189P | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPIN4 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF37A | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 37/114 reads (32%) | called by muse, varscan2
- ZNF37A | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- ACTL6B | c.768C>T p.I256= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV50514713; called by muse, mutect2, varscan2
- ADAM30 | c.312T>A p.P104= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV65560992; called by muse, mutect2, varscan2
- ADGRD1 | c.915C>T p.L305= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs1350473608, COSV55444260; called by muse, mutect2, varscan2
- AHCTF1 | c.3801A>T p.S1267= (on ENST00000366508; = p.S1241= on NM_015446.5) | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV58249394; called by muse, mutect2, varscan2
- CMTR1 | c.1110G>A p.E370= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV65089716, COSV65090255; called by muse, mutect2, varscan2
- COL5A3 | c.2130A>G p.G710= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV53410100; called by muse, mutect2, varscan2
- DRC1 | c.28C>T p.L10= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1428813195; called by muse, mutect2
- DSC1 | c.174G>C p.S58= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs767775240, COSV57141767; called by muse, mutect2, varscan2
- GJB4 | c.375C>T p.G125= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs147830069; called by muse, mutect2, varscan2
- GLI2 | c.3756C>T p.S1252= (on ENST00000361492 / NM_001374353.1; = p.S1269= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as COSV58040849; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.114G>A p.R38= (on ENST00000354667 / NM_031243.3; = p.R26= on NM_002137.4) | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV61158908; called by muse, mutect2, varscan2
- KBTBD3 | c.1461T>C p.S487= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as COSV73241384; called by muse, mutect2, varscan2
- LPAR6 | c.948C>T p.F316= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV57303361, COSV57307458, COSV99926504; called by muse, mutect2, varscan2
- LRTM2 | c.399G>A p.R133= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs1426936565, COSV54564838; called by muse, mutect2, varscan2
- MICB | c.1110G>C p.L370= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV52856389, COSV99357480; called by muse, mutect2, varscan2
- MYH10 | c.2424G>A p.K808= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs1329039432, COSV52600188; called by muse, mutect2
- PC | c.927C>G p.T309= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100852249, COSV63080313; called by muse, mutect2, varscan2
- PRAG1 | c.369G>A p.P123= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as rs749659111, COSV58160406; called by muse, mutect2, varscan2
- PRXL2B | c.586C>T p.L196= (on ENST00000444521; = p.L148= on NM_152371.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV56521115; called by muse, mutect2, varscan2
- PSMA7 | c.252C>T p.I84= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV53380264; called by muse, mutect2, varscan2
- REEP5 | c.36C>T p.F12= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV54841797; called by muse, mutect2
- SDHA | c.1320G>A p.E440= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV53767797; called by muse, mutect2, varscan2
- SH3PXD2B | c.1083G>A p.P361= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as rs1299021796, COSV61125825; called by muse, mutect2, varscan2
- SLC46A2 | c.363C>T p.L121= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as rs1181171945, COSV65289954; called by muse, mutect2, varscan2
- SLC6A3 | c.1578G>T p.L526= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV54363893; called by muse, mutect2, varscan2
- SORBS1 | c.1623C>A p.G541= (on ENST00000361941 / NM_001034954.2; = p.G331= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV53356942; called by muse, mutect2, varscan2
- SQSTM1 | c.1317G>A p.P439= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as rs11548636, COSV52972947; called by muse, mutect2, varscan2
- TDRD9 | c.1698C>T p.I566= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV59146362; called by muse, mutect2, varscan2
- TMEM208 | c.120G>A p.V40= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV50760357; called by muse, mutect2, varscan2
- ZNF671 | c.735A>G p.K245= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs547014796, COSV58052468; called by muse, mutect2, varscan2
- ZZEF1 | c.6663C>T p.V2221= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- NEFM | c.-1G>A | 5'UTR (SNP) | VAF 4/9 reads (44%) | catalogued as rs768012895, COSV99647183; called by muse, varscan2
- PTN | c.-70C>T | 5'UTR (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100780826; called by muse, mutect2, varscan2
- RBM44 | c.-98-2229G>A | Intron (SNP) | VAF 29/50 reads (58%) | catalogued as COSV57629242; called by muse, mutect2, varscan2
